Gene-level copy-number profile of tumor specimen TCGA-KL-8339-01A from TCGA case TCGA-KL-8339, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 67.2 years (24,545 days).
Specimen TCGA-KL-8339-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KICH.d20e310a-d98d-45fb-8882-d4d8740e9490.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KL-8339-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0fbc2d8b-11f0-4be2-b191-7dadef5d8fd9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 893; copy number 2: 21,938; copy number 3: 5,499; copy number 4: 26,701; copy number 5: 4,742; copy number 6: 3; copy number 7: 14; copy number 11: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KL-8339-01A-11D-2308-01): tumor purity 0.91, ploidy 3.25, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–46,870, 1 gene: FAM110C.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 24 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:107,312,132–108,498,384, 24 genes, copy number 11 (within-gene range 7–11): AP000766.1, CWF19L2, SMARCE1P1, ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A, AP003307.1, CUL5, Y_RNA, AP002433.1, ACAT1, AP002433.2, NPAT, ATM, Y_RNA, C11orf65, POGLUT3.

Autosomal genes at a single copy (total copy number 1): 893. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
